CCDI case PBCKVM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c5a96a47-8ced-4c6e-ad14-b35f45aa9ae0

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,083 days).

Biospecimens (3 samples)
- Sample 0DUB6A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUB89: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUB9N: Tissue type: Tumor; Specimen type: Solid Tissue.
